Somatic mutation profile of tumor specimen MP2PRT-PARKKL-TMP1-A (aliquot MP2PRT-PARKKL-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARKKL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,293 days).
Specimen MP2PRT-PARKKL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9b639eb-adf1-4a22-9f91-083e8dcd05fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKKL-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKKL-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fd90cdc-d241-4aca-9c7d-3a57640841ea

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, Nonsense Mutation 6, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 28/309 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: pathogenic; called by muse, mutect2
- ALMS1 | c.8965C>G p.Q2989E | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV52516683; called by muse, mutect2
- ARID1A | c.4675G>A p.A1559T | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.344); catalogued as rs745476438; called by muse, mutect2
- BIRC5 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs1175422196, COSV56955816; called by muse, mutect2, varscan2
- DSCAM | c.3712G>A p.E1238K | Missense Mutation (SNP) | VAF 28/722 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV68021943, COSV68038961; called by muse, mutect2
- ESYT3 | c.1777T>C p.Y593H | Missense Mutation (SNP) | VAF 159/349 reads (46%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.88); catalogued as rs758434905; called by muse, mutect2, varscan2
- FSIP2 | c.6848C>G p.S2283* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as COSV58090589; called by muse, mutect2
- IKZF2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 144/512 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.146); catalogued as COSV100563346; called by muse, mutect2, varscan2
- NRXN1 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 264/829 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV68021714; called by muse, mutect2, varscan2
- PCDHB10 | c.1030C>G p.P344A | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV53377308, COSV99503917; called by muse, mutect2
- PPHLN1 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.915); catalogued as COSV56729293; called by muse, mutect2
- RXFP1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs368154635; called by muse, mutect2, varscan2
- SART1 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 31/533 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV56713281; called by muse, mutect2
- SLC6A19 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 33/578 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs183474162; called by muse, mutect2
- SPIDR | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52389973; called by muse, mutect2, varscan2
- TAS2R42 | c.690G>C p.R230S | Missense Mutation (SNP) | VAF 39/420 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV62084559; called by muse, mutect2
- TTK | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as COSV57881385; called by muse, mutect2, varscan2
- UHRF1 | c.1178C>T p.S393L (on ENST00000612630 / NM_001290050.1; = p.S406L on NM_013282.4) | Missense Mutation (SNP) | VAF 77/360 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53575738; called by muse, mutect2, varscan2
- ZMAT5 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 74/415 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100722617; called by muse, mutect2, varscan2
- AP1G1 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2
- AP2B1 | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ATP5F1B | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.013); called by muse, varscan2
- CWC27 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1H1 | c.13218G>C p.K4406N | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EMILIN1 | c.1913C>G p.S638* | Nonsense Mutation (SNP) | VAF 62/547 reads (11%) | called by muse, mutect2, varscan2
- EPHA6 | c.1954G>A p.G652R (on ENST00000389672 / NM_001080448.3; = p.G44R on NM_173655.4) | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXB13 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 43/491 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- HPGD | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEPCE | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 89/530 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MEPCE | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 116/580 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NTN3 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 74/989 reads (7%) | called by muse, mutect2
- OR5AC2 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PASD1 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, varscan2
- PDCD11 | c.4544A>T p.N1515I | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX11G | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PMS1 | c.2340G>C p.E780D | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PPWD1 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2
- PREP | c.991C>G p.Q331E (on ENST00000369110; = p.Q397E on NM_002726.5) | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRRT2 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 56/802 reads (7%) | called by muse, mutect2
- RPS12 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 39/185 reads (21%) | called by muse, mutect2, varscan2
- SART1 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- SEC23IP | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 86/457 reads (19%) | called by muse, mutect2, varscan2
- SLC4A8 | c.2401C>G p.Q801E | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A3 | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 40/716 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- SMARCC1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- SNRNP35 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 90/546 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STAG2 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- TUBA1B | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VWCE | c.1829C>A p.S610Y | Missense Mutation (SNP) | VAF 26/507 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ZNF254 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- ANO1 | c.60C>T p.I20= | Silent (SNP) | VAF 99/577 reads (17%) | called by muse, mutect2, varscan2
- DAB2IP | c.3105C>T p.L1035= (on ENST00000408936; = p.L1007= on NM_032552.3) | Silent (SNP) | VAF 21/415 reads (5%) | catalogued as rs1469311493; called by muse, mutect2
- EIF3G | c.177C>T p.V59= | Silent (SNP) | VAF 24/432 reads (6%) | called by muse, mutect2
- KIAA1549 | c.1926G>A p.S642= | Silent (SNP) | VAF 148/350 reads (42%) | catalogued as rs764962649; called by muse, mutect2, varscan2
- KLK4 | c.573C>T p.F191= | Silent (SNP) | VAF 50/425 reads (12%) | called by muse, mutect2, varscan2
- LRRC1 | c.1131G>C p.L377= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- LSS | c.744G>C p.L248= | Silent (SNP) | VAF 124/1257 reads (10%) | called by muse, mutect2, varscan2
- MEPCE | c.1369C>T p.L457= | Silent (SNP) | VAF 125/619 reads (20%) | catalogued as rs146851898; called by muse, mutect2, varscan2
- MKI67 | c.4080A>G p.E1360= | Silent (SNP) | VAF 196/486 reads (40%) | called by muse, mutect2, varscan2
- PCDH17 | c.3189C>A p.A1063= | Silent (SNP) | VAF 108/579 reads (19%) | called by muse, mutect2, varscan2
- PPP1R35 | c.363G>A p.G121= | Silent (SNP) | VAF 93/565 reads (16%) | called by muse, mutect2, varscan2
- PRSS23 | c.960C>G p.V320= | Silent (SNP) | VAF 38/538 reads (7%) | catalogued as rs1377443324; called by muse, mutect2
- RSPH10B | c.2502C>T p.L834= | Silent (SNP) | VAF 70/508 reads (14%) | called by muse, mutect2, varscan2
- SCN3A | c.5802G>C p.G1934= | Silent (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- SLC36A1 | c.699C>G p.V233= | Silent (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- SMYD4 | c.1737G>A p.R579= | Silent (SNP) | VAF 48/355 reads (14%) | catalogued as rs1000175689; called by muse, mutect2, varscan2
- STRA6 | c.525C>T p.L175= | Silent (SNP) | VAF 39/672 reads (6%) | catalogued as rs563498564, COSV60587884; called by muse, mutect2
- TDRD6 | c.4149C>G p.L1383= | Silent (SNP) | VAF 33/310 reads (11%) | called by muse, mutect2
- TEX36 | c.459T>C p.A153= | Silent (SNP) | VAF 119/311 reads (38%) | called by muse, mutect2, varscan2
- THNSL2 | c.183C>T p.L61= | Silent (SNP) | VAF 69/310 reads (22%) | catalogued as COSV100147711; called by muse, mutect2, varscan2
- PRAC2 | c.-6G>C | 5'UTR (SNP) | VAF 33/436 reads (8%) | called by muse, mutect2
